Surgical pathology report (de-identified scan), TCGA case TCGA-CM-5864, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-5864-01A (Primary Tumor).

[page 1 of 4]
....

Clinical Diagnosis & History:
CRC of ascending colon.

Specimens Submitted:
1: SP: Right colon, partial colectomy
2: SP: Portion of omentum

DIAGNOSIS:

1. SP: Right colon, partial colectomy:

Tumor Type:

Adenocarcinoma

Histologic Grade:

Moderately differentiated

Tumor Location:

Cecum

Tumor Size:

Length is 6.5 cm

Width is 10 cm

Maximal thickness is 2.0 cm

Tumor Budding:

Absent

Increased Tumor Infiltrating Lymphocytes:

Absent

Precursor Lesions:

Tubulovillous adenoma

Deepest Tumor Invasion:

Muscularis propria

Gross Tumor Perforation:

Not identified

Lymphovascular Invasion:

Not identified

Large Venous Invasion:

Not Identified

Perineural Invasion:

Not identified

Surgical Margins:

Free of tumor

Polypos/Mucosa Dysplasia (away from the carcinoma):

Not Identified

Non-Neoplastic Bowel:

** Continued on next page **

[page 2 of 4]
Unremarkable

Appendix:

Unremarkable

Lymph Nodes:

Number with metastasis: 0

Total number examined: 33

Tumor deposits in pericorectal soft tissue:

Not Identified

Tumor Staging (AJCC 7th Edition):

pT2 (Tumor invades muscularis propria)

Lymph Node Stage (AJCC 7th Edition):

N0 (No regional lymph node metastasis)

2. PORTION OF OMENTUM, EXCISION:
- BENIGN MATURE ADIPOSE TISSUE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

1). The specimen is received fresh, labeled "Right colon" and consists of a segment of terminal ileum, cecum with attached appendix and ascending colon. The terminal ileum measures nine cm in length and five cm in circumference at the proximal resected margin. The remaining colon measures 24 in length with a circumference of 8.5 cm at the distal resected margin. The attached appendix measures six cm in length and averages 0.7 cm in diameter. The appendiceal and intestinal serosa is pink tan and smooth. Focally hemorrhagic lobulated yellow tan adipose tissue spans the length of the specimen measuring up to five cm in thickness. The specimen is opened to reveal a large sessile lesion measuring 6.5 cm in length, 10 cm in width, and to 2 cm in thickness. The mass is located in the cecum, eight cm from the proximal margin and 18 cm from the distal margin. Sectioning reveals probable invasion into the submucosa. There is questionable muscularis propria invasion and the tumor does not appear to invade through the muscularis propria. The depth of invasion is 0.2 cm grossly. The remaining mucosa is tan with normal folds. The attached adipose tissue is thoroughly examined and all identified lymph nodes are submitted. Representative sections of the specimen are submitted for permanent sections and for TPS.

Summary of sections:

P - proximal margin shave

D - distal margin shave

T - tumor

A - appendix representative sections

** Continued on next page **

[page 3 of 4]
RS -representative sections
LN - lymph nodes
BLN - bisected lymph nodes
TLN-trisected lymph node
SLN-one lymph node sectioned

2). The specimen is received fresh, labeled "Portion of omentum." It consists of a 16.0 x 11.0 x 0.5 cm portion of lobulated adipose tissue consistent with omentum. Serial sectioning reveals a lobulated surface. Representative sections are submitted.

Summary of sections:
O - omentum

Summary of Sections:
Part 1: SP: Right colon, partial colectomy

Block	Sect.	Site	PCs
1		A	3
5		BLN	10
1		D	1
9		LN	27
1		P	1
1		RS	2
3		SLN	5
10		T	10
1		TLN	3

Part 2: SP: Portion of omentum

Block	Sect.	Site	PCs
2		O	4

Procedures/Addenda:

Addendum

Date Ordered:

Date Complete:

Date Reported:

Addendum Diagnosis

#1) SITE: LARGE BOWEL

- IMMUNOHISTOCHEMICAL STAINING FOR DNA MISMATCH REPAIR PROTEINS HAS BEEN PERFORMED PER CLINICAL REQUEST. THE RESULTS ARE AS FOLLOWS:

MLH1: STAINING PRESENT IN TUMOR

MSH2: STAINING PRESENT IN TUMOR

** Continued on next page **

[page 4 of 4]
MSH6: STAINING PRESENT IN TUMOR

PMS2: STAINING PRESENT IN TUMOR

CONCLUSION: IMMUNOHISTOCHEMICAL STAINING FOR THE TESTED DNA MISMATCH REPAIR
PROTEINS IS RETAINED IN THE TUMOR.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing.

** End of Report **

Source: NCI Genomic Data Commons file 6c57edef-1063-4dbd-a4dd-30be6c32f472 (TCGA-CM-5864.0FC4D13C-EFCF-413F-A922-0E88089FA055.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).